Surgical pathology report (de-identified scan), TCGA case TCGA-XV-A9W5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Capital Biosciences, specimen TCGA-XV-A9W5-01A (Primary Tumor).

Pathology Report

Date:

Patient ID:

Age:

Sex: M

Clinical Dx: Melanoma

Tumor Location: Skin

Localization: Left shoulder

Source: Epithelial melanoma

Clark Level (1-5): 4

Breslow (mm): 2

Tumor: 2

Normal: 0

Metastasis: 0

Stage (I-IV): I

Tumor size (mm x mm): 3x2

NeoAdj ImmunoTx: No

ICD-O-3

Melanoma NOS 8720/3
Site: L Shoulder NOS
C44.6
QV 3/12/14

Source: NCI Genomic Data Commons file 80845c48-75de-4ca8-81d9-2000d91b212e (TCGA-XV-A9W5.F2915AF4-7C62-4510-A02A-D0AB7C896FA0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).